Somatic mutation profile of tumor specimen TCGA-N8-A4PM-01A (aliquot TCGA-N8-A4PM-01A-11D-A28R-08) from TCGA case TCGA-N8-A4PM, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IB; Age at diagnosis: 73.8 years (26,971 days).
Specimen TCGA-N8-A4PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e675151b-fd84-41e3-90d8-25f4478dd201.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A4PM-10A (Blood Derived Normal), aliquot TCGA-N8-A4PM-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/686d30df-f6d1-4a86-a7d2-ace4e69af433

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 2, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 61/133 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- LAMA1 | c.7180C>T p.R2394* | Nonsense Mutation (SNP) | VAF 54/102 reads (53%) | catalogued as rs542213899, COSV101055124; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 24/60 reads (40%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 39/79 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABR | c.2094C>A p.F698L (on ENST00000302538 / NM_021962.5; = p.F661L on NM_001092.5) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV52141393; called by muse, mutect2, varscan2
- ADAMTS16 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs199521777; called by muse, mutect2, varscan2
- ARR3 | c.102C>T p.D34= | Splice Region (SNP) | VAF 25/29 reads (86%) | catalogued as rs773410236; called by muse, mutect2, varscan2
- CARMIL2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1428762094, COSV100575957; called by muse, mutect2, varscan2
- CATSPER1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs200189507; called by muse, mutect2, varscan2
- CCDC88B | c.1766C>A p.P589Q | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.32); catalogued as COSV57266401; called by muse, mutect2, varscan2
- CHD4 | c.3295T>C p.F1099L (on ENST00000357008 / NM_001363606.2; = p.F1112L on NM_001273.5) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58894723; called by muse, mutect2, varscan2
- CTSC | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs775201891; called by muse, mutect2, varscan2
- DEPDC7 | c.173G>A p.R58H (on ENST00000241051 / NM_001077242.2; = p.R49H on NM_139160.2) | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs552446140, COSV53805982; called by muse, mutect2, varscan2
- EMSY | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs758335223; called by muse, mutect2, varscan2
- F10 | c.70+1G>A p.X24_splice | Splice Site (SNP) | VAF 38/56 reads (68%) | catalogued as rs746084152, CS054887; called by muse, mutect2, varscan2
- HERC1 | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs775255598, COSV71247721; called by muse, mutect2, varscan2
- HS3ST6 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs561297247, COSV53534215; called by muse, mutect2, varscan2
- NDN | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs767312463, COSV59358381; called by muse, mutect2, varscan2
- PATJ | c.4933G>A p.A1645T | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs757517839; called by muse, mutect2, varscan2
- PCDHA6 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as COSV65343926; called by muse, varscan2
- PRXL2A | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142605674; called by muse, mutect2, varscan2
- RARG | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143739684; called by muse, mutect2, varscan2
- RGS12 | c.3617G>A p.R1206H | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375895098; called by muse, mutect2, varscan2
- SH3GL3 | c.833C>A p.T278K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as COSV61056344; called by muse, mutect2, varscan2
- TMTC4 | c.346A>G p.S116G (on ENST00000376234 / NM_001350577.2; = p.S135G on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV60893397; called by muse, mutect2, varscan2
- TSPAN33 | c.509A>T p.Y170F | Missense Mutation (SNP) | VAF 110/186 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56826174; called by muse, mutect2, varscan2
- ZDBF2 | c.6713A>T p.Y2238F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV65624877; called by muse, mutect2, varscan2
- ZNF831 | c.3073dup p.D1025Gfs*9 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | catalogued as rs775554241; called by mutect2, varscan2
- AHNAK | c.7946C>A p.P2649H | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALCAM | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ANKRD12 | c.6163G>T p.D2055Y | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP35 | c.1952del p.F651Sfs*24 | Frame Shift Del (DEL) | VAF 44/113 reads (39%) | called by mutect2, pindel, varscan2
- CLEC17A | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERBIN | c.3757-2A>G p.X1253_splice (on ENST00000284037 / NM_001253697.2; = p.X1212_splice on NM_018695.4) | Splice Site (SNP) | VAF 32/50 reads (64%) | called by mutect2, varscan2
- HLA-C | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.371); called by muse, mutect2
- LRRC4 | c.20dup p.T8Nfs*47 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- TACC2 | c.2126G>T p.R709I | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TGFB1 | c.656T>G p.L219R | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TP53 | c.362_363del p.S121Cfs*27 | Frame Shift Del (DEL) | VAF 61/88 reads (69%) | called by mutect2, pindel, varscan2
- TPX2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC7B | c.1041G>T p.R347S | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TUT7 | c.2153G>A p.S718N | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UBXN7 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZBTB7A | c.1194_1198del p.R399Hfs*139 | Frame Shift Del (DEL) | VAF 3/39 reads (8%) | called by mutect2, pindel
- ZFP36L1 | c.194_221del p.N65Sfs*6 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- DCLK1 | c.496C>T p.L166= | Silent (SNP) | VAF 59/116 reads (51%) | catalogued as rs757915614; called by muse, mutect2, varscan2
- DISP3 | c.2811C>T p.F937= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as rs776634246, COSV53825449; called by muse, mutect2, varscan2
- FZD2 | c.1200C>G p.G400= | Silent (SNP) | VAF 89/97 reads (92%) | catalogued as COSV59529774; called by muse, mutect2, varscan2
- IL1RL2 | c.111T>C p.P37= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs770349785; called by muse, mutect2, varscan2
- KEL | c.1362C>T p.L454= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- KIAA2013 | c.777G>T p.V259= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs769251819; called by muse, mutect2, varscan2
- MYF5 | c.450A>T p.G150= | Silent (SNP) | VAF 98/240 reads (41%) | called by muse, mutect2, varscan2
- MYH7 | c.4974C>T p.D1658= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs374289523; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- NIPA2 | c.493T>C p.L165= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs746423708; called by muse, mutect2, varscan2
- NLRP8 | c.582G>A p.L194= | Silent (SNP) | VAF 58/109 reads (53%) | catalogued as rs771030080; called by muse, mutect2, varscan2
- OR4A16 | c.157T>C p.L53= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV59044607; called by muse, mutect2, varscan2
- OXGR1 | c.222C>T p.N74= | Silent (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1923C>T p.D641= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs1554135806, COSV65342003; called by muse, mutect2, varscan2
- PCDHGB2 | c.1803C>T p.N601= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as rs778338184, COSV99531734; called by muse, mutect2, varscan2
- TDRD10 | c.366G>A p.P122= | Silent (SNP) | VAF 92/200 reads (46%) | catalogued as rs907639076, COSV63813057; called by muse, mutect2, varscan2
- SNORD116-20 | n.32T>A | RNA (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
